Surgical pathology report (de-identified scan), TCGA case TCGA-61-1730, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-61-1730-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: LEFT ADNEXA, BILATERAL SALPINGO-OOPHORECTOMY -

- A. SEROUS CARCINOMA, HIGH GRADE, WITH ASSOCIATED NECROSIS IN A BACKGROUND OF LOW MALIGNANT POTENTIAL TUMOR AND ADENOFIBROMA.
- B. THE TUMOR MEASURES 16CM (GROSS MEASUREMENT) (SEE COMMENT-1).
- C. NO DEFINITIVE LYMPHOVASCULAR INVASION IDENTIFIED.
- D. CAPSULAR RUTURE IS GROSSLY IDENTIFIED.
- E. FALLOPIAN TUBE WITH NO SPECIFIC PATHOLOGICAL CHANGES.

PART 2: RIGHT ADNEXA, BILATERAL SALPINGO-OOPHORECTOMY -

- A. OVARY WITH PHYSIOLOGICAL CHANGES, NO TUMOR SEEN.
- B. FALLOPIAN TUBE WITH NO SPECIFIC PATHOLOGICAL CHANGES.

PART 3: UTERUS, TOTAL ABDOMINAL HYSTERECTOMY (56 GRAMS) -

- A. ENDOMETRIAL POLYP MEASURING 2.7 CM.
- B. DISORDERED PROLIFERATIVE ENDOMETRIUM.
- C. LEIOMYOMATA UPTO 1.5CM.
- D. ENDOCERVIX WITH SQUAMOUS METAPLASIA AND CHRONIC CERVICITIS.
- E. UNREMARKABLE ECTOCERVIX.

PART 4: LEFT PELVIC LYMPH NODES, BIOPSY -

FIVE BENIGN LYMPH NODES, NEGATIVE FOR TUMOR (0/5).

PART 5: LEFT COMMON LYMPH NODES, BIOPSY -

ONE BENIGN LYMPH NODE, NEGATIVE FOR TUMOR(0/1).

PART 6: LEFT PERIAORTIC LYMPH NODES, BIOPSY -

ONE BENIGN REACTIVE LYMPH NODE, NEGATIVE FOR TUMOR (0/1).

PART 7: POSTERIOR CUL-DE-SAC BIOPSY -

FIBROADIPOSE TISSUE WITH MESOTHELIAL HYPERPLASIA, NEGATIVE FOR TUMOR (SEE COMMENT-2)

PART 8: OMENTUM -

FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

PART 9: APPENDIX, BIOPSY -

APPENDIX WITH FIBROUS OBLITERATION OF THE LUMEN, NO TUMOR SEEN.

COMMENT:

#1: The tumor shows an expansile form of invasion more than an invasive pattern and associated with extensive necrosis. It is difficult to assess the demarcation from the LMP to invasive carcinoma on histology.

#2: The mesothelial cells are positive for Calretinin and negativity for Ber-EP4, confirms the groups and sheets of cells present in biopsy sample are mesothelial cells.

#3: The abdominal ascetic fluid cytology is positive for malignant cells.

#4: This case is reviewed by who agrees with the diagnosis.

CASE SYNOPSIS:

SYNOPTIC - PRIMARY OVARIAN TUMORS INCLUDING BORDERLINE TUMORS

TUMOR LOCATION:	Left
PROCEDURE:	Bilateral Salpingo-oophorectomy
TUMOR SIZE:	Maximum dimension: 16 cm
TUMOR TYPE:	Papillary serous carcinoma
HISTOLOGIC SILVERBERG GRADE:	Poorly differentiated (8-9 pts)
ARCHITECTURAL PATTERN:	Papillary (2)
CYTOLOGIC ATYPIA:	Marked (3)
MITOTIC COUNTS / 10hpf:	10-24 (2)
VASCULAR INVASION:	No
TUMOR CAPSULE:	Ruptured
SURFACE IMPLANTS:	Not present
MALIGNANT CELLS IN ASCITES OR PERITONEAL WASHING:	Yes
LYMPH NODES EXAMINED:	Total number of lymph nodes examined: 7
LYMPH NODES POSITIVE:	Number of positive lymph nodes, Right: 0 Number of positive lymph nodes, Left: 0
LYMPH NODE GROUPS INVOLVED:	Pelvic, Left, Common iliac, Left, Para-aortic, Left
EXTRANODAL EXTENSION:	No
T STAGE, PATHOLOGIC:	pT1c
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	pMX

Source: NCI Genomic Data Commons file 9284ac95-21a1-4e2f-bc69-b445305714f4 (TCGA-61-1730.4624968A-27C1-4F4F-B9F1-3E6997C15A21.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).